Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A2MZ, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A2MZ-01A (Primary Tumor).

Print Malignancy History		☒
Reviewer Initials	BB	D. No Reviewed: 8/2/11

10/8/11

SPECIMEN TAKEN:

* This report has been amended! *

FINAL DIAGNOSIS ----- Pathologist:

1. RIGHT SUPERIOR PARATHYROID (BX): PARATHYROID TISSUE (5 MG).
2. RIGHT THYROID LOBE (TOTAL THYROIDECTOMY):

SPECIMEN TYPE:

Total thyroidectomy

TUMOR SITE:

Right lobe

HISTOLOGIC TYPE:

Papillary carcinoma

TUMOR SIZE:

1.2 cm

FOCALITY:

Unifocal

LYMPH NODES:

All 6 lymph nodes are negative for tumor

EXTENT OF INVASION

PRIMARY TUMOR:

pT1b

REGIONAL LYMPH NODES:

pNO: No regional lymph node metastasis

MARGINS:

Margins are uninvolved

VENOUS/LYMPHATIC INVASION:

Absent

ADDITIONAL PATHOLOGIC FINDINGS:

None identified.

NOTE: Right inferior parathyroid tissue is identified in two adjacent sections (F&G).

AMENDED THE SIZE OF THE TUMOR AND THE STAGE FROM "3 CM" TO "1.2 CM" IN BOTH THE GROSS AND MICROSCOPIC, AS A RESULT OF A TYPOGRAPHICAL ERROR IN THE INITIAL GROSS DESCRIPTION.

Source: NCI Genomic Data Commons file 5c2abd59-292b-4d4e-9792-469cd4b4a70e (TCGA-ET-A2MZ.DC5C5C67-07E0-46A6-8CB8-1355237BE056.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).